Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHC, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHC-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 7,0 cm; no angio-invasion; no invasion of rete testis;
no invasion of tunica albuginea.

Date of procurement (= date of orchidectomy):

ICD O 3

Seminoma NOS 9061/3
Site: Testis NOS C62.9
9/3/7/14

pathologist

professor of pathology

Criteria	hw 1/18/14	Yes	No
Dual/Synchronous Pathology Noted			

Source: NCI Genomic Data Commons file 9fb68d93-35f4-4183-8b2b-4b1a0298561c (TCGA-2G-AAHC.95EE635D-5E7E-40F9-A847-8F26B1DCEADB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).